TCGA case TCGA-2Y-A9H6 — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bc3502bc-bbf6-44f2-a1f4-d1567819aefb

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Alive.

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 68.4 years (24,982 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 357 days.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: Yes; Vascular invasion type: Macro.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
2. Prior malignancy of the uterus (histology not recorded by GDC). Age at diagnosis: 62.6 years (22,868 days); Days to diagnosis: -2,114 days (-5.8 years); AJCC staging edition: 6th; AJCC pathologic stage: Stage I.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -2,114 days (-5.8 years); Treatment anatomic sites: Cervix / Fallopian Tube / Ovary / Uterus.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- ECOG performance status: 0.
- Follow-up contact recording only the day: day 357.

Molecular and laboratory tests
- Alpha Fetoprotein 114 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 7].
- Prothrombin Time 10.5 Seconds [Blood test normal range lower: 8.3; Blood test normal range upper: 11.5].
- Creatinine 1.8 mg/dL [Blood test normal range lower: 0.8; Blood test normal range upper: 1.5].
- Albumin 4 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].
- Platelets 224 (unit not recorded by GDC) [Blood test normal range lower: 143; Blood test normal range upper: 382].
- Total Bilirubin 0.3 mg/dL [Blood test normal range lower: 0.3; Blood test normal range upper: 1.3].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Alcohol Consumption.
- Timepoint category: Initial Diagnosis; Weight: 99 kg; Height: 156 cm; BMI: 40.7.

Family history
- Relatives with cancer history count: 1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2Y-A9H6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 100 mg.
  Slide TCGA-2Y-A9H6-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-2Y-A9H6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2Y-A9H6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Single; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: Yes.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Uterus; Other malignancy histological type: Endometerial.
- Other malignancy form, Surgery: Other malignancy surgery type: Tah/bso.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 357 days; disease-specific survival: no event (censored), 357 days; disease-free interval: no event (censored), 357 days; progression-free interval: no event (censored), 357 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2Y-A9H6-01A-11D-A38W-01): tumor purity 0.67, ploidy 1.91, whole-genome doublings 0.
